Somatic mutation profile of tumor specimen MMRF_2187_1_PB_CD138pos (aliquot MMRF_2187_1_PB_CD138pos_T2_KHS5U_L09499) from MMRF case MMRF_2187, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.5 years (19,528 days).
Specimen MMRF_2187_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e00ad74-a0a1-4ea6-a82d-910d75d0a965.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2187_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2187_1_PB_CD3pos_C3_KHS5U_L09498; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a75e3ba-5eb5-4464-b46d-92b74aee8ede

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, 3'UTR 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NADSYN1 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs775486610; called by muse, mutect2, varscan2
- TACR3 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1215592649, COSV59207768; called by muse, mutect2
- MROH2A | c.2730A>C p.Q910H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); called by mutect2, varscan2
- SS18L2 | c.217del p.S73Qfs*13 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- AC093802.1 | n.1914+8516C>T | Intron (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- BRWD1 | c.-158del | 5'UTR (DEL) | VAF 14/74 reads (19%) | catalogued as rs1481534556; called by pindel, varscan2
- NT5E | c.*164A>C | 3'UTR (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.*1656C>T | 3'UTR (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2
- TTC7B | c.1237-33T>C | Intron (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
